Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4352, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4352-01A (Primary Tumor).

[page 1 of 3]
TCGA-BP-4352

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

- 1: KIDNEY AND PARTIAL ADRENAL, RIGHT; TOTAL NEPHRECTOMY AND PARTIAL ADRENALECTOMY
- 2: LYMPH NODES, PARACAVAL; EXCISION
- 3: LYMPH NODES, HILUM; EXCISION

DIAGNOSIS:

1. KIDNEY AND PARTIAL ADRENAL, RIGHT; TOTAL NEPHRECTOMY AND PARTIAL ADRENALECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with extensive (>75%) sarcomatoid differentiation

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 10 cm.

Local Invasion (for renal cortical types):

Involves Gerota's fascia

Extends into renal pelvis

Involves renal sinus fat

Involves renal hilar fat

(Forms polypoid mass protruding into renal pelvis without ulcerating the epithelium)

Renal Vein Invasion:

Identified

Small vessel angiolymphatic invasion also identified.

Surgical Margins:

Tumor present at soft tissue margin

Non-Neoplastic Kidney:

Mild arteriosclerotic changes

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

2. LYMPH NODES, PARACAVAL; EXCISION:

Lymph Nodes:

Number of nodes examined:1

Number of metastatic nodes:0

3. LYMPH NODES, HILUM; EXCISION:

Lymph Nodes:

Number of nodes examined:9

Number of metastatic nodes:0

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CA-1X.	
	CD10	
	NEG CONT	
	IMM RECUT	

Gross Description:

1).The specimen is received fresh labeled "right kidney and partial adrenal " and consists of a kidney with attached ureter, renal vessels, partial adrenal and perinephric fat weighing 607 g in total. The kidney measures 14.5 x 10.0 x 7.0 cm. The attached ureter measures 8.0 cm in length and 0.2 cm in diameter. The attached renal vein measures 1.5 cm in length and 2.0 cm in diameter. The renal vessel and ureteric margins are grossly free of tumor. A partial adrenal gland is identified, measuring 4.0 x 0.9 x 0.2 cm and weighing 1.06 g. The kidney is inked black and bivalved to reveal a 10.0 x 10.0 x 6.5 cm tumor. Sectioning reveals tan-red to orange yellow, focally necrotic soft areas and gray white firm areas. The tumor grossly extends to the perirenal fat. All of the surgical margins are grossly negative. A tumor embolus is identified in the renal vein. A 0.4 cm in diameter tan nodule is identified on the pelvic mucosa. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. The adrenal gland is grossly unremarkable. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections with nodule

K -- representative sections kidney

AD -- adrenal gland

RVT -- renal vein with tumor thrombus

2). The specimen is received in formalin, labeled "Paracaval lymph nodes" and consists of a single lymph node measuring 2 x 1.3 x 0.8 cm. The lymph node is sectioned and entirely submitted.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Summary of sections:

LN- lymph node

3). The specimen is received in formalin labeled "Hilum and lymph nodes". It consists of multiple lymph nodes ranging from 0.3 x 0.3 cm up to 2.0 cm x 1.5 cm in greatest dimensions. The lymph nodes are entirely submitted.

Summary of sections:

LN-lymph nodes

LN1-lymph node number one

LN2-lymph node number two

Summary of Sections:

Part 1: KIDNEY AND PARTIAL ADRENAL, RIGHT; TOTAL NEPHRECTOMY AND PARTIAL ADRENALECTOMY

Block	Sect. Site	PCs
1	ad	1
1	k	1
1	rp	1
1	rvt	1
10	t	10
1	thf	1
2	tk	2
1	tsf	1
1	uvm	1

Part 2: LYMPH NODES, PARACAVAL; EXCISION

Block	Sect. Site	PCs
2	ln	2

Part 3: LYMPH NODES, HILUM; EXCISION

Block	Sect. Site	PCs
2	ln	2
2	ln1	2
1	ln2	1

Source: NCI Genomic Data Commons file 1d105f17-0629-4a16-b1dd-0c91b74b04ad (TCGA-BP-4352.05B4FE97-CC88-434C-8866-1DD3F2DD9A6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).